Gene-level copy-number profile of tumor specimen ALCH-B6F0-TTP1-A from ALCHEMIST case ALCH-B6F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.3 years (29,697 days).
Specimen ALCH-B6F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 453dd384-b8ee-420b-83bf-26386be81168.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6F0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/d148bbe2-d282-470b-a596-594e2a2269c4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 45; copy number 2: 4,388; copy number 3: 4,902; copy number 4: 40,649; copy number 5: 3,695; copy number 6: 1,151; copy number 7: 552; copy number 8: 2,957; copy number 10: 27.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr22:21,473,000–21,551,461, 4 genes (within-gene range 0–2): PI4KAP2, AP000557.1, RN7SKP221, RIMBP3C.
- chr22:21,555,138–21,555,457, 1 gene (within-gene range 0–2): Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,249,300–1,745,171, 14 genes, copy number 10 (within-gene range 6–10): CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129.
- chr4:3,293,028–3,890,249, 13 genes, copy number 10: RGS12, AL645949.1, AL645949.2, HGFAC, DOK7, LRPAP1, AL590235.1, LINC00955, AL121796.1, LINC02171, LINC02600, ADRA2C, OR7E163P.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
